Somatic mutation profile of tumor specimen 0DOV9Q from CCDI case PBCBXV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.4 years (4,149 days).
Specimen 0DOV9Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6315b8e5-4195-4b3b-81fe-923ffc0160a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOV8G (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ffb19f2-016f-45f7-82f9-d7041183f8bc

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H2AZ1 | c.313A>G p.I105V | Missense Mutation (SNP) | VAF 30/939 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV56454962; called by muse, mutect2
- FBXO34 | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 24/419 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2
- SF3A2 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 24/360 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.84); called by muse, mutect2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 7/136 reads (5%) | called by muse, mutect2
- SORBS2 | c.3134+57A>G | Intron (SNP) | VAF 76/304 reads (25%) | called by muse, mutect2
